Somatic mutation profile of tumor specimen 0DSEZJ from CCDI case PBCHEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 13.5 years (4,937 days).
Specimen 0DSEZJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32b83563-76cd-40d9-ad85-9953ceccf3e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca1d9c6e-4d70-4159-bb6f-33e4168905ac

The open-access MAF lists 88 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Intron 8, Nonsense Mutation 5, Frame Shift Ins 3, 3'UTR 3, Splice Region 1, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 301/566 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1847G>T p.R616I | Missense Mutation (SNP) | VAF 151/1126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58054614; called by mutect2, varscan2
- ACIN1 | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 314/755 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773407941; called by muse, mutect2, varscan2
- AVPR1B | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149082642; called by muse, mutect2, varscan2
- BCORL1 | c.3889C>T p.R1297* | Nonsense Mutation (SNP) | VAF 399/474 reads (84%) | catalogued as COSV54389895; called by muse, mutect2, varscan2
- CACNA1H | c.6229C>T p.R2077C | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs376607278; called by muse, mutect2, varscan2
- CRB1 | c.678C>G p.D226E | Missense Mutation (SNP) | VAF 48/921 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV66337716; called by muse, mutect2
- DOCK3 | c.2854C>A p.L952I | Missense Mutation (SNP) | VAF 116/575 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99815004; called by muse, mutect2, varscan2
- EDEM3 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 218/1233 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs1558054481; called by muse, mutect2, varscan2
- FGF2 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs761725675; called by muse, mutect2, varscan2
- IQCK | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 62/916 reads (7%) | catalogued as COSV57524613; called by muse, mutect2
- LRP2 | c.11629C>A p.L3877M | Missense Mutation (SNP) | VAF 203/1187 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.789); catalogued as COSV99785903; called by muse, mutect2, varscan2
- LSM14A | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 223/838 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1318143812; called by muse, mutect2, varscan2
- MSH6 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 127/1013 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs181727939, COSV52274073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 151/867 reads (17%) | catalogued as COSV56305778, COSV56310713, COSV99842969; called by muse, mutect2, varscan2
- NBAS | c.1987C>A p.Q663K | Missense Mutation (SNP) | VAF 117/995 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs761330483, COSV55714898; called by muse, mutect2, varscan2
- NLRP6 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.21); catalogued as COSV56458892; called by mutect2, varscan2
- NOS3 | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 223/756 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.025); catalogued as rs564937301; called by muse, mutect2, varscan2
- OBSCN | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 52/758 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV52761679; called by muse, mutect2
- PCDHA4 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 38/242 reads (16%) | catalogued as rs1554124750; called by muse, mutect2
- PIRT | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 156/795 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.809); catalogued as rs774699130; called by muse, mutect2, varscan2
- PLCXD3 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 118/512 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1248830262; called by muse, mutect2, varscan2
- PLEKHG7 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 161/1150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774991604, COSV60822757; called by muse, mutect2, varscan2
- SEPTIN10 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 117/993 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs1046944748; called by muse, mutect2, varscan2
- SLC25A17 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 174/1892 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54351691; called by muse, mutect2
- SLC25A41 | c.810G>C p.W270C | Missense Mutation (SNP) | VAF 99/636 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1185118956; called by muse, mutect2, varscan2
- SLCO5A1 | c.2465C>A p.P822Q | Missense Mutation (SNP) | VAF 266/805 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs369446842; called by muse, mutect2, varscan2
- SPTBN2 | c.4638C>A p.D1546E | Missense Mutation (SNP) | VAF 59/486 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.732); catalogued as rs554183492; called by muse, mutect2, varscan2
- TMEM63C | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53610024; called by muse, mutect2, varscan2
- TRIM49C | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 6/267 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV71511012; called by muse, mutect2
- ADSS2 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 227/627 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by mutect2, varscan2
- ALKBH8 | c.811_827dup p.R277Qfs*11 | Frame Shift Ins (INS) | VAF 256/1034 reads (25%) | called by mutect2, varscan2
- AP3S1 | c.198A>C p.R66S | Missense Mutation (SNP) | VAF 28/1106 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AR | c.1594T>C p.S532P | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ASIC5 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 36/1422 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- BAZ2A | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 198/756 reads (26%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CASP8AP2 | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 122/659 reads (19%) | called by muse, mutect2, varscan2
- CCDC141 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 126/962 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CHD6 | c.6347G>T p.S2116I | Missense Mutation (SNP) | VAF 145/819 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- COX11 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 445/885 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ECT2L | c.2219C>A p.A740E | Missense Mutation (SNP) | VAF 222/579 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.2632C>G p.L878V | Missense Mutation (SNP) | VAF 152/1038 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM161A | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 80/725 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM219B | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- GGCX | c.195dup p.V66Cfs*29 | Frame Shift Ins (INS) | VAF 167/1048 reads (16%) | called by mutect2, pindel, varscan2
- GLUD2 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 364/434 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KIF24 | c.3461G>C p.C1154S | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA5 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LIG4 | c.1088G>T p.C363F | Missense Mutation (SNP) | VAF 112/2195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MARS1 | c.877_881dup p.F294Lfs*36 | Frame Shift Ins (INS) | VAF 140/910 reads (15%) | called by mutect2, pindel, varscan2
- MYO1G | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 120/1097 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEK11 | c.647+8G>A | Splice Region (SNP) | VAF 136/483 reads (28%) | called by muse, mutect2, varscan2
- OR11G2 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 122/745 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OR5B3 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 154/959 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PSMC2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 149/1677 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC5A9 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 90/601 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAP1 | c.140C>A p.T47K | Missense Mutation (SNP) | VAF 118/857 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STAT2 | c.2119C>A p.Q707K | Missense Mutation (SNP) | VAF 132/1168 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by mutect2, varscan2
- ZNF469 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- BTBD8 | c.3096A>C p.S1032= (on ENST00000636805 / NM_001376131.1; = p.S519= on NM_015237.4) | Silent (SNP) | VAF 255/1281 reads (20%) | called by muse, mutect2, varscan2
- CPZ | c.819C>T p.N273= (on ENST00000360986 / NM_001014447.3; = p.N262= on NM_003652.3) | Silent (SNP) | VAF 75/413 reads (18%) | catalogued as rs1313883785; called by muse, mutect2, varscan2
- DHX38 | c.3117G>T p.R1039= | Silent (SNP) | VAF 47/745 reads (6%) | called by muse, mutect2
- HDLBP | c.2205G>A p.K735= | Silent (SNP) | VAF 288/948 reads (30%) | called by muse, mutect2, varscan2
- NWD2 | c.4278C>G p.L1426= | Silent (SNP) | VAF 149/887 reads (17%) | catalogued as COSV58748212; called by muse, mutect2, varscan2
- PFKFB3 | c.1539C>T p.S513= | Silent (SNP) | VAF 59/856 reads (7%) | catalogued as rs1422693189, COSV57987199; called by muse, mutect2
- PKHD1L1 | c.2394C>G p.L798= | Silent (SNP) | VAF 142/1335 reads (11%) | called by muse, mutect2, varscan2
- PLA2R1 | c.2421G>A p.P807= | Silent (SNP) | VAF 166/1068 reads (16%) | catalogued as rs771945277, COSV99323114; called by muse, mutect2
- POMGNT1 | c.1461C>A p.G487= | Silent (SNP) | VAF 90/617 reads (15%) | called by muse, mutect2, varscan2
- PRH2 | c.33G>A p.L11= | Silent (SNP) | VAF 101/1856 reads (5%) | called by muse, mutect2
- SCAMP1 | c.393T>A p.P131= | Silent (SNP) | VAF 34/1061 reads (3%) | catalogued as COSV57242179; called by muse, mutect2
- SLC6A12 | c.1086G>T p.L362= | Silent (SNP) | VAF 85/755 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.16275C>T p.A5425= (on ENST00000367255 / NM_182961.4; = p.A5354= on NM_033071.3) | Silent (SNP) | VAF 42/1393 reads (3%) | called by muse, mutect2
- TAS2R39 | c.906C>A p.A302= | Silent (SNP) | VAF 88/1682 reads (5%) | called by muse, mutect2
- ASAH1 | c.126+682A>G | Intron (SNP) | VAF 258/788 reads (33%) | catalogued as rs1244873903; called by muse, mutect2, varscan2
- BCL9L | c.*3697T>C | 3'UTR (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- C8orf33 | c.551-34C>G | Intron (SNP) | VAF 34/753 reads (5%) | called by muse, mutect2
- HSH2D | c.216-73G>A | Intron (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2, varscan2
- LINC02872 | n.171C>G | RNA (SNP) | VAF 54/718 reads (8%) | called by muse, mutect2
- POLR2J3 | c.50+17G>T | Intron (SNP) | VAF 72/2291 reads (3%) | catalogued as rs1301307564; called by muse, mutect2
- SFTPA1 | c.-23-109C>T | Intron (SNP) | VAF 15/463 reads (3%) | catalogued as rs988806977; called by muse, mutect2
- TMEM87A | c.1062+99G>T | Intron (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- UBE2Q2L | chr15:84172494 C>G | 5'Flank (SNP) | VAF 50/802 reads (6%) | called by muse, varscan2
- WNK1 | c.2140-2424G>A | Intron (SNP) | VAF 355/1141 reads (31%) | catalogued as rs1277687516; called by muse, mutect2, varscan2
- XPO1 | c.2023-61A>C | Intron (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- ZIC2 | c.-23A>C | 5'UTR (SNP) | VAF 38/335 reads (11%) | called by muse, mutect2, varscan2
- ZNF142 | c.*4077G>T | 3'UTR (SNP) | VAF 55/269 reads (20%) | called by muse, mutect2, varscan2
- ZNF383 | c.*87A>G | 3'UTR (SNP) | VAF 37/340 reads (11%) | called by muse, mutect2, varscan2
